Surgical pathology report (de-identified scan), TCGA case TCGA-86-8075, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8075-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

		OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path
Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy
Tumor site: Lung
Tumor size: 2.6 x 1.5 x 1.5
cm
Histologic type:
Adenocarcinoma
Histologic grade:
Moderately differentiated
Tumor extent: Visceral
pleura
Other tumor nodules: Not
specified
Lymph nodes: 0/3 positive
for metastasis (Regional
0/3)
Lymphatic invasion: Not
specified
Venous invasion: Not
specified
Margins: Not specified
Evidence of neo-adjuvant
treatment: Not specified
Additional pathologic
findings: Not specified
Comments: None

Laterality

Left-upper

Excision date

Source: NCI Genomic Data Commons file f42305b9-592a-45f9-88c9-9dbbcab00c1f (TCGA-86-8075.7988F9A9-584E-4CE9-B12C-F3E289AF1D6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).